Somatic mutation profile of tumor specimen C3N-00514-02 (aliquot CPT0077930007_1) from CPTAC case C3N-00514, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.4 years (22,057 days).
Specimen C3N-00514-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 759b6c40-32b7-4812-891c-415ad60b216f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00514-31 (Blood Derived Normal), aliquot CPT0077990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7170a8f-c58c-4bf6-9904-799fbaa4527f

The open-access MAF lists 49 somatic variants for this specimen: 28 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 16, Intron 3, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 105/792 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 29/558 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54025106; called by muse, mutect2
- BCL11A | c.1087C>T p.R363C (on ENST00000335712 / NM_001365609.1; = p.R397C on NM_018014.4) | Missense Mutation (SNP) | VAF 82/1168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59624433; called by muse, mutect2
- CHST15 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 38/671 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs201960331; called by muse, mutect2
- CTNNA2 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 34/572 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63587511; called by muse, mutect2
- EPHA8 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 73/1266 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.404); catalogued as rs369076646; called by muse, mutect2
- EVC2 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 44/804 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs145758016, COSV60388597; ClinVar: uncertain significance; called by muse, mutect2
- HDAC4 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 68/920 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs61754650; called by muse, mutect2
- IGLV7-43 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 36/471 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.614); catalogued as rs188344205; called by muse, mutect2
- MON1A | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV56560120; called by muse, mutect2
- NLRC5 | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 83/1027 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs61744164; called by muse, mutect2
- PCDHA5 | c.1603A>T p.S535C | Missense Mutation (SNP) | VAF 164/2325 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100972296; called by muse, mutect2
- POM121L12 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 43/565 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.798); catalogued as rs746175412, COSV68692799; called by muse, mutect2
- POMK | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 70/881 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.339); catalogued as COSV100505838; called by muse, mutect2
- PYGM | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 58/1092 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs781394907, COSV51217665; called by muse, mutect2
- RNF150 | c.259C>A p.R87S | Missense Mutation (SNP) | VAF 48/736 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV100154337; called by muse, mutect2
- ROBO3 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 37/572 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs746486301; called by muse, mutect2
- SLC19A1 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs749244983; called by muse, mutect2
- SLC6A4 | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 41/452 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs190758123, COSV55565955; called by muse, mutect2
- TTN | c.70087C>T p.R23363C (on ENST00000591111; = p.R15939C on NM_003319.4) | Missense Mutation (SNP) | VAF 22/336 reads (7%) | PolyPhen possibly damaging (0.727); catalogued as rs1320326326, COSV59934151; called by muse, mutect2
- ZNF605 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as rs1387671853; called by muse, mutect2
- BRSK2 | c.1345G>C p.V449L | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRIA1 | c.2641C>T p.H881Y | Missense Mutation (SNP) | VAF 72/1092 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.209); called by muse, mutect2
- PCCB | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2
- SETD2 | c.1751A>G p.Q584R | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2
- TFE3 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.17639A>G p.E5880G (on ENST00000591111; = p.E4953G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/308 reads (6%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- USP7 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AHNAK2 | c.7815C>T p.P2605= | Silent (SNP) | VAF 104/1216 reads (9%) | catalogued as rs374259207; called by muse, mutect2
- BEND4 | c.627C>T p.N209= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs574971489, COSV72468915; called by muse, mutect2, varscan2
- C1QC | c.642C>T p.G214= | Silent (SNP) | VAF 40/461 reads (9%) | catalogued as rs778815928; called by muse, mutect2
- COL5A1 | c.1113C>T p.G371= | Silent (SNP) | VAF 80/1082 reads (7%) | catalogued as rs754423580; called by muse, mutect2
- CRAT | c.315C>T p.T105= | Silent (SNP) | VAF 31/450 reads (7%) | catalogued as rs959328458; called by muse, mutect2
- DMWD | c.1575G>A p.T525= | Silent (SNP) | VAF 22/239 reads (9%) | catalogued as rs778487763; called by muse, mutect2
- FLNB | c.5496G>A p.V1832= | Silent (SNP) | VAF 95/1081 reads (9%) | called by muse, mutect2
- GRM6 | c.408G>A p.P136= | Silent (SNP) | VAF 21/236 reads (9%) | catalogued as COSV51445887; called by muse, mutect2
- IRX2 | c.669C>T p.H223= | Silent (SNP) | VAF 76/1048 reads (7%) | catalogued as rs753207229; called by muse, mutect2
- LGR5 | c.2502G>A p.L834= | Silent (SNP) | VAF 27/398 reads (7%) | called by muse, mutect2
- MTOR | c.24C>T p.A8= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as rs779391809, COSV63868114; called by muse, mutect2
- OBSCN | c.17283C>T p.C5761= | Silent (SNP) | VAF 128/1660 reads (8%) | catalogued as rs752645262; called by muse, mutect2
- RNF10 | c.1656C>T p.S552= | Silent (SNP) | VAF 29/433 reads (7%) | called by muse, mutect2
- SOX11 | c.531C>T p.G177= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as rs373041001, COSV100430678; called by muse, mutect2, varscan2
- WT1 | c.1002G>A p.T334= | Silent (SNP) | VAF 90/1446 reads (6%) | catalogued as rs1260693060; ClinVar: likely benign; called by muse, mutect2
- ZDHHC14 | c.945G>A p.L315= | Silent (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- DNAH14 | c.6033+2184C>T | Intron (SNP) | VAF 28/629 reads (4%) | called by muse, mutect2
- MAD1L1 | c.1999-31536C>T | Intron (SNP) | VAF 26/346 reads (8%) | catalogued as rs1232521229; called by muse, mutect2
- MAPK1IP1L | c.-134C>T | 5'UTR (SNP) | VAF 74/976 reads (8%) | catalogued as rs767344249; called by muse, mutect2
- NSMF | c.1132-56C>T | Intron (SNP) | VAF 70/854 reads (8%) | catalogued as rs1200349338; called by muse, mutect2
- RAB18 | c.*4029C>A | 3'UTR (SNP) | VAF 60/840 reads (7%) | called by muse, mutect2
